Somatic mutation profile of tumor specimen TCGA-EE-A2GR-06A (aliquot TCGA-EE-A2GR-06A-11D-A197-08) from TCGA case TCGA-EE-A2GR, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 79.2 years (28,910 days).
Specimen TCGA-EE-A2GR-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63bb908e-0ee2-4566-80fd-78ca76f52184.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2GR-10A (Blood Derived Normal), aliquot TCGA-EE-A2GR-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62e446b0-32d2-4042-ad47-8bcf22efa822

The open-access MAF lists 1,923 somatic variants for this specimen: 1,216 protein-altering or splice-affecting, 662 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,093, Silent 662, Nonsense Mutation 70, Intron 19, Splice Region 17, Splice Site 15, RNA 14, Frame Shift Del 13, 5'Flank 6, 3'UTR 4, Nonstop Mutation 4, 3'Flank 2.

Variants (750 of 1,923; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAI2 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs137853226, COSV56492973; ClinVar: pathogenic; called by muse, mutect2
- GRIN2A | c.2041C>T p.R681* | Nonsense Mutation (SNP) | VAF 18/55 reads (33%) | catalogued as rs397518472, CM138216, COSV58045574, COSV58045723; ClinVar: pathogenic; called by mutect2, varscan2
- NGLY1 | c.1624C>T p.R542* | Nonsense Mutation (SNP) | VAF 22/42 reads (52%) | catalogued as rs528583612, CM146810, COSV54983506; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1403C>T p.T468M | Missense Mutation (SNP) | VAF 40/70 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs121918457, CM021672, COSV61005439; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP63 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 26/45 reads (58%) | catalogued as rs900140738, COSV53196111; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.672A>T p.E224D | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV51056055; called by mutect2, varscan2
- A4GALT | c.876G>A p.W292* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV50743979; called by muse, mutect2, varscan2
- ABCA12 | c.5167G>A p.G1723R (on ENST00000272895 / NM_173076.3; = p.G1405R on NM_015657.3) | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0.1); catalogued as rs1445487352, COSV55979754; called by muse, varscan2
- ABCA12 | c.1267C>T p.P423S (on ENST00000272895 / NM_173076.3; = p.P105S on NM_015657.3) | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV55966596, COSV55979772; called by muse, mutect2, varscan2
- ABCA4 | c.2839G>A p.D947N | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.044); catalogued as rs1324891342, COSV64679468; called by muse, mutect2, varscan2
- ABCB4 | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs1021988376, CM075951, COSV55943140; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC10 | c.2254C>T p.P752S (on ENST00000372530 / NM_001198934.2; = p.P724S on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55095058; called by muse, mutect2, varscan2
- ABCC12 | c.3072G>A p.W1024* | Nonsense Mutation (SNP) | VAF 22/93 reads (24%) | catalogued as COSV60919209; called by muse, mutect2, varscan2
- ABCC3 | c.1741C>T p.P581S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53331029; called by muse, mutect2
- ABCC6 | c.2674A>T p.K892* | Nonsense Mutation (SNP) | VAF 33/66 reads (50%) | catalogued as COSV52748704; called by muse, mutect2, varscan2
- ABHD12B | c.575C>T p.T192I (on ENST00000337334 / NM_001206673.2; = p.T115I on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs202134253; called by muse, mutect2, varscan2
- ABHD15 | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1354940955, COSV99975236; called by muse, mutect2
- ABHD15 | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99975237; called by mutect2, varscan2
- ABHD8 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); catalogued as rs1213946271, COSV53113580; called by muse, mutect2, varscan2
- ACE | c.1429G>A p.G477R | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.4); catalogued as COSV52013644, COSV52014505; called by muse, mutect2, varscan2
- ACOX2 | c.545G>A p.S182N | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV57151425; called by muse, mutect2, varscan2
- ACP3 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 69/151 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.066); catalogued as rs777654881, COSV60484679; called by muse, mutect2, varscan2
- ACTR1B | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs571901265, COSV56705895; called by muse, mutect2, varscan2
- ADAM18 | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 58/111 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55847852; called by muse, mutect2, varscan2
- ADAM28 | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.255); catalogued as COSV56106676; called by muse, varscan2
- ADAM28 | c.907G>A p.G303R | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56106693; called by muse, mutect2, varscan2
- ADAM33 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV62936195; called by muse, mutect2, varscan2
- ADAM9 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV65963048; called by muse, mutect2, varscan2
- ADAMTS17 | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV51496413; called by muse, mutect2, varscan2
- ADAMTS20 | c.4067C>T p.P1356L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV67141326; called by muse, mutect2, varscan2
- ADAMTS20 | c.3118G>A p.G1040R | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770107831, COSV67141333; called by muse, mutect2, varscan2
- ADAMTS6 | c.3227C>T p.P1076L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.405); catalogued as COSV58685118; called by muse, mutect2, varscan2
- ADAMTS9 | c.1541T>G p.L514R | Missense Mutation (SNP) | VAF 207/525 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV99898623; called by muse, mutect2, varscan2
- ADAMTS9 | c.1540C>T p.L514F | Missense Mutation (SNP) | VAF 211/527 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV99898626; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4117C>T p.P1373S | Missense Mutation (SNP) | VAF 28/31 reads (90%) | SIFT tolerated (0.24); PolyPhen benign (0.214); catalogued as COSV65879385; called by muse, mutect2, varscan2
- ADCY7 | c.3076G>A p.G1026R | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54271626; called by muse, mutect2, varscan2
- ADD1 | c.1573T>C p.C525R | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV53275535; called by muse, mutect2, varscan2
- ADD2 | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1558526530, COSV52456622, COSV52462275; called by mutect2, varscan2
- ADGRF4 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs771530266, COSV51951749, COSV51955542; called by muse, mutect2, varscan2
- ADGRG4 | c.6286G>A p.D2096N | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0.19); catalogued as COSV54961462, COSV99796142; called by muse, mutect2, varscan2
- ADGRG4 | c.6677C>T p.S2226F | Missense Mutation (SNP) | VAF 51/52 reads (98%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs746417313, COSV54969511; called by muse, mutect2, varscan2
- ADGRG7 | c.1475C>T p.S492F | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as COSV56302131; called by muse, mutect2, varscan2
- ADGRL4 | c.1001C>T p.S334L | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.297); catalogued as COSV66066989; called by muse, mutect2, varscan2
- ADGRV1 | c.3173G>A p.G1058E | Missense Mutation (SNP) | VAF 62/96 reads (65%) | SIFT tolerated (0.14); PolyPhen benign (0.072); catalogued as COSV67988852; called by muse, mutect2, varscan2
- ADH1B | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59299295; called by muse, mutect2, varscan2
- ADNP2 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV51542970; called by muse, varscan2
- ADRB1 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs551795534, COSV65168398; called by muse, mutect2, varscan2
- AFF3 | c.3430C>T p.P1144S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.426); catalogued as COSV57878397; called by muse, mutect2, varscan2
- AFF3 | c.1861C>T p.P621S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV100417486; called by mutect2, varscan2
- AFG1L | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64558890; called by mutect2, varscan2
- AGA | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 90/151 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV52807836; called by muse, mutect2, varscan2
- AGBL2 | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 39/41 reads (95%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as COSV54094127; called by muse, mutect2, varscan2
- AGGF1 | c.1120A>G p.T374A | Missense Mutation (SNP) | VAF 210/324 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57231555; called by muse, mutect2, varscan2
- AGPS | c.428A>C p.K143T | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV51566628; called by muse, mutect2, varscan2
- AICDA | c.538C>T p.L180F | Missense Mutation (SNP) | VAF 77/173 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57563422, COSV57566722; called by muse, mutect2, varscan2
- AK7 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV50884931; called by mutect2, varscan2
- AL031777.2 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious, low confidence (0); catalogued as COSV61911631; called by muse, mutect2, varscan2
- ALDH1L2 | c.1048-2A>G p.X350_splice | Splice Site (SNP) | VAF 8/24 reads (33%) | catalogued as COSV51560686; called by muse, mutect2, varscan2
- ALDH3B1 | c.647C>A p.P216H | Missense Mutation (SNP) | VAF 66/115 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50292189; called by muse, varscan2
- ALDH3B2 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs139967003; called by muse, mutect2, varscan2
- ALG6 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs1425794381, COSV54763704, COSV54768248; called by muse, mutect2, varscan2
- ALLC | c.1066G>A p.G356R | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157557204, COSV52994498; called by mutect2, varscan2
- ALLC | c.1067G>A p.G356E | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99377406; called by muse, mutect2, varscan2
- ALOX5 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1184151327, COSV65555095; called by muse, mutect2
- ALOX5 | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768049838, COSV65552889; called by mutect2, varscan2
- ALOXE3 | c.2003C>T p.P668L | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs748508111, COSV59073761; called by mutect2, varscan2
- ALOXE3 | c.2002C>T p.P668S | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV100559595; called by muse, mutect2, varscan2
- ALPL | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.387); catalogued as rs753550135, COSV66379351; called by mutect2, varscan2
- AMBN | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.697); catalogued as COSV59828431; called by muse, mutect2, varscan2
- ANAPC4 | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV59546798; called by muse, mutect2, varscan2
- ANAPC5 | c.1832C>T p.S611F | Missense Mutation (SNP) | VAF 242/543 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as rs1197921890, COSV55845862; called by muse, mutect2, varscan2
- ANGPT1 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52433501; called by mutect2, varscan2
- ANK1 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV55881725; called by muse, mutect2, varscan2
- ANK3 | c.12118G>A p.E4040K | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.566); catalogued as rs201115226, COSV55050851; called by muse, mutect2, varscan2
- ANKRD34B | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs865774055, COSV58613353; called by muse, mutect2, varscan2
- ANKS1A | c.481C>T p.H161Y | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64460547; called by muse, mutect2, varscan2
- ANO1 | c.1944G>A p.M648I | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100303647; called by muse, mutect2, varscan2
- ANO4 | c.628C>T p.R210W (on ENST00000392977 / NM_001286615.2; = p.R175W on NM_178826.4) | Missense Mutation (SNP) | VAF 51/206 reads (25%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.719); catalogued as rs372521580; called by muse, mutect2, varscan2
- ANO5 | c.879G>A p.K293= | Splice Region (SNP) | VAF 9/27 reads (33%) | catalogued as COSV61086199; called by muse, mutect2, varscan2
- AOAH | c.558T>G p.D186E | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51752076; called by muse, mutect2, varscan2
- AOX1 | c.1612G>A p.D538N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs756638287, COSV65984723; called by muse, mutect2, varscan2
- APC | c.3107T>G p.L1036W | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99964937; called by muse, mutect2, varscan2
- APC | c.3108G>T p.L1036F | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99964939; called by mutect2, varscan2
- APOA5 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 68/72 reads (94%) | SIFT tolerated (0.17); PolyPhen benign (0.112); catalogued as rs574363219, COSV57065605; called by muse, mutect2, varscan2
- APOB | c.3221G>A p.G1074E | Missense Mutation (SNP) | VAF 134/374 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51957221; called by muse, mutect2, varscan2
- ARFGEF3 | c.4915G>A p.E1639K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV52473159; called by muse, mutect2, varscan2
- ARHGAP21 | c.2527C>A p.P843T | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57612113; called by mutect2, varscan2
- ARHGAP24 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV67846659; called by muse, mutect2, varscan2
- ARHGEF16 | c.2021G>A p.G674E | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101000327; called by muse, mutect2, varscan2
- ARHGEF26 | c.1655C>T p.S552F | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV62852843; called by muse, mutect2, varscan2
- ARID1B | c.6325C>T p.R2109C | Missense Mutation (SNP) | VAF 91/226 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51684555; called by muse, mutect2, varscan2
- ARL3 | c.240T>A p.N80K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.154); catalogued as COSV53301462; called by muse, mutect2, varscan2
- ARMC1 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV52533669; called by mutect2, varscan2
- ARMC3 | c.148T>A p.Y50N | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV53058586, COSV53069373; called by muse, mutect2, varscan2
- ARMC3 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV53064127; called by muse, mutect2, varscan2
- ARMC4 | c.1472G>A p.R491K | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as COSV59467798; called by muse, mutect2, varscan2
- ARNTL | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 61/168 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62989295; called by muse, mutect2, varscan2
- ARNTL2 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.821); catalogued as COSV53829529; called by muse, mutect2, varscan2
- ASAP3 | c.2464C>T p.L822F | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.102); catalogued as COSV60878708; called by muse, mutect2, varscan2
- ASF1B | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs1201983925, COSV54615595; called by muse, varscan2
- ASH1L | c.7426C>T p.P2476S (on ENST00000368346 / NM_001366177.2; = p.P2471S on NM_018489.3) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0); catalogued as COSV64214929; called by muse, mutect2, varscan2
- ASIC2 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as COSV56771843; called by mutect2, varscan2
- ASMT | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV101172435, COSV67110460; called by muse, mutect2, varscan2
- ASPM | c.2503C>A p.L835I | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54141217; called by muse, mutect2, varscan2
- ASTN1 | c.2678C>T p.S893F | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as rs745642391, COSV62502443; called by muse, mutect2, varscan2
- ASXL3 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV52478934; called by muse, mutect2, varscan2
- ASXL3 | c.4517G>A p.R1506K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.978); catalogued as COSV52482825; called by muse, mutect2, varscan2
- ATF6B | c.1990C>T p.P664S | Missense Mutation (SNP) | VAF 48/422 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs267600974, COSV64352853; called by muse, mutect2, varscan2
- ATF7IP2 | c.273C>A p.F91L | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs1361151528, COSV61092378, COSV61095454; called by mutect2, varscan2
- ATM | c.1288T>A p.C430S | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV53781306; called by muse, mutect2, varscan2
- ATP10D | c.2864G>A p.G955E | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56714303; called by muse, mutect2, varscan2
- ATP13A4 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs777828353, COSV55068396, COSV99794497; called by muse, mutect2, varscan2
- ATP2A3 | c.1015G>A p.V339M | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1263674493, COSV59236227; called by muse, mutect2, varscan2
- ATP2C2 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs267604666, COSV52294600; called by muse, mutect2, varscan2
- ATP2C2 | c.1591C>T p.P531S | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.31); catalogued as rs747948688, COSV52294038, COSV52302341; called by muse, mutect2, varscan2
- ATP6V1E2 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); catalogued as COSV60576614, COSV60576800; called by muse, mutect2, varscan2
- ATP8B2 | c.1409C>T p.S470F (on ENST00000672630; = p.S437F on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100527619; called by muse, mutect2, varscan2
- ATP8B4 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV52726399; called by mutect2, varscan2
- ATPAF2 | c.869G>T p.*290Lext*10 | Nonstop Mutation (SNP) | VAF 16/67 reads (24%) | catalogued as COSV58262590, COSV58267071; called by mutect2, varscan2
- AXDND1 | c.495G>A p.K165= | Splice Region (SNP) | VAF 20/60 reads (33%) | catalogued as COSV62650465; called by muse, mutect2
- AXDND1 | c.2659G>A p.E887K | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV62650471; called by muse, mutect2, varscan2
- AXL | c.2167G>A p.D723N (on ENST00000301178 / NM_021913.5; = p.D714N on NM_001699.6) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV56576194; called by muse, mutect2, varscan2
- AXL | c.2542C>T p.P848S (on ENST00000301178 / NM_021913.5; = p.P839S on NM_001699.6) | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT tolerated (0.14); PolyPhen benign (0.077); catalogued as COSV99995815; called by muse, mutect2, varscan2
- AXL | c.2543C>T p.P848L (on ENST00000301178 / NM_021913.5; = p.P839L on NM_001699.6) | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV99995819; called by muse, mutect2, varscan2
- AZU1 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT tolerated (0.23); PolyPhen benign (0.118); catalogued as COSV52142934; called by muse, mutect2, varscan2
- B3GALT1 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV59910212; called by muse, mutect2, varscan2
- BICD2 | c.2174C>T p.T725I | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63551323; called by muse, mutect2, varscan2
- BIN2 | c.312G>A p.W104* | Nonsense Mutation (SNP) | VAF 39/144 reads (27%) | catalogued as COSV57208616; called by muse, mutect2, varscan2
- BIRC6 | c.7522C>T p.L2508F | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.68); catalogued as COSV101427744, COSV70207554; called by muse, mutect2, varscan2
- BIRC6 | c.8683G>A p.G2895R | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101427780; called by muse, mutect2, varscan2
- BIRC6 | c.8684G>A p.G2895E | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101427782; called by muse, mutect2, varscan2
- BOC | c.2704C>T p.P902S | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs754960188, COSV99847956; called by muse, mutect2, varscan2
- BOC | c.2705C>T p.P902L | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs765131607, COSV56347943; called by mutect2, varscan2
- BRINP1 | c.1942T>C p.F648L | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV56315807; called by muse, mutect2, varscan2
- BRINP2 | c.1905G>A p.W635* | Nonsense Mutation (SNP) | VAF 25/51 reads (49%) | catalogued as COSV64181003; called by muse, mutect2, varscan2
- BRINP3 | c.2081G>A p.G694E | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as rs539178233, COSV66544173; called by muse, mutect2, varscan2
- BRINP3 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs367902400, COSV66524676; called by muse, mutect2, varscan2
- BTAF1 | c.4903G>A p.E1635K | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.053); catalogued as rs773772641, COSV56432730; called by muse, mutect2, varscan2
- BZW1 | c.502C>T p.L168F | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs370242551; called by muse, mutect2, varscan2
- C10orf88 | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV64404313; called by muse, mutect2, varscan2
- C12orf42 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59392240; called by muse, mutect2, varscan2
- C17orf67 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 144/577 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67375554; called by muse, mutect2, varscan2
- C19orf57 | c.32G>T p.G11V | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1440313904, COSV60970704; called by mutect2, varscan2
- C1orf105 | c.156G>A p.M52I | Missense Mutation (SNP) | VAF 69/142 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV51129632; called by muse, varscan2
- C1orf105 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs1220882896, COSV51131400; called by muse, varscan2
- C1orf127 | c.1934C>T p.S645F | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.389); catalogued as COSV65439359; called by muse, mutect2, varscan2
- C2CD3 | c.5621C>T p.S1874L | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV58103059; called by mutect2, varscan2
- C3 | c.2803G>A p.G935R | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55582165; called by muse, mutect2, varscan2
- C4orf17 | c.691C>T p.H231Y | Missense Mutation (SNP) | VAF 75/151 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.259); catalogued as COSV58513824; called by muse, mutect2, varscan2
- C5 | c.3616C>T p.R1206C | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1402957355, COSV56324454; called by muse, mutect2, varscan2
- C7 | c.1139G>A p.G380E | Missense Mutation (SNP) | VAF 66/114 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57482775; called by muse, varscan2
- CACNA1E | c.3743G>A p.G1248E | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62437717; called by muse, mutect2, varscan2
- CACNA1E | c.5074G>A p.E1692K | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.094); catalogued as rs770455581, COSV62437732; called by muse, varscan2
- CACNA2D3 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 56/106 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs552100021, COSV55568277; called by muse, mutect2, varscan2
- CACNA2D3 | c.1870C>T p.H624Y | Missense Mutation (SNP) | VAF 52/242 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.134); catalogued as COSV55589780; called by muse, varscan2
- CACNB2 | c.505G>A p.E169K (on ENST00000324631 / NM_201596.3; = p.E114K on NM_000724.4) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV56651315; called by mutect2, varscan2
- CALN1 | c.283G>A p.D95N (on ENST00000329008 / NM_001017440.3; = p.D137N on NM_031468.4) | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs1465311917, COSV61156764; called by muse, mutect2, varscan2
- CAMK1G | c.93-1G>A p.X31_splice | Splice Site (SNP) | VAF 24/48 reads (50%) | catalogued as rs1270846335, COSV50528007; called by muse, mutect2, varscan2
- CAMTA1 | c.3671C>T p.P1224L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV57924949, COSV57933074; called by muse, mutect2, varscan2
- CAPN5 | c.1894C>A p.L632M (on ENST00000456580; = p.L592M on NM_004055.5) | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.277); catalogued as COSV99581665; called by mutect2, varscan2
- CASP10 | c.1118C>T p.P373L (on ENST00000272879 / NM_032974.5; = p.P330L on NM_001230.5) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV53781109; called by muse, mutect2, varscan2
- CASR | c.1459G>A p.E487K (on ENST00000490131; = p.E564K on NM_000388.4) | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.355); catalogued as COSV56142279; called by mutect2, varscan2
- CAVIN4 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV56868691; called by muse, mutect2, varscan2
- CCDC114 | c.1352T>G p.L451R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as COSV59559222; called by muse, mutect2, varscan2
- CCDC170 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV53346382; called by muse, mutect2, varscan2
- CCDC50 | c.1051G>A p.D351N (on ENST00000392455 / NM_178335.3; = p.D175N on NM_174908.4) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101165240; called by mutect2, varscan2
- CCDC60 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59545358; called by muse, mutect2, varscan2
- CCDC66 | c.2092C>T p.P698S (on ENST00000394672 / NM_001353147.1; = p.P664S on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.95); PolyPhen benign (0.005); catalogued as COSV58310771; called by muse, mutect2, varscan2
- CCDC89 | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV57035118; called by muse, mutect2, varscan2
- CCKAR | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55164552; called by muse, mutect2, varscan2
- CCNT1 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV56066461; called by muse, mutect2, varscan2
- CCSER1 | c.840G>A p.M280I | Missense Mutation (SNP) | VAF 88/216 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV61427815, COSV61477231; called by muse, mutect2, varscan2
- CD177 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.07); catalogued as COSV65122830; called by muse, mutect2, varscan2
- CD19 | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.217); catalogued as rs763500099, COSV61190081; called by muse, mutect2, varscan2
- CD1E | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63771001; called by muse, varscan2
- CD248 | c.2122G>T p.V708L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV60936927, COSV60938164; called by muse, mutect2, varscan2
- CD2AP | c.1745C>T p.S582F | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs879462082, COSV63759167, COSV63762212; called by muse, mutect2, varscan2
- CD4 | c.154C>T p.H52Y | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.585); catalogued as COSV50597197, COSV99163945; called by muse, mutect2
- CD69 | c.493T>C p.F165L | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV57304075; called by muse, mutect2, varscan2
- CD93 | c.1522G>A p.G508S | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV99848844; called by muse, mutect2, varscan2
- CDH12 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66427735; called by muse, mutect2, varscan2
- CDH19 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs1317594506, COSV50982813; called by muse, varscan2
- CDH24 | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs758602279, COSV57464328; called by muse, mutect2, varscan2
- CDH5 | c.920C>T p.T307I | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as COSV58520513; called by muse, mutect2, varscan2
- CDH8 | c.2228C>T p.S743F | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs957180578, COSV54892269, COSV54907000; called by muse, mutect2, varscan2
- CDS1 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55691434; called by muse, mutect2, varscan2
- CEACAM3 | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as rs200718992, COSV55761765; called by muse, mutect2, varscan2
- CEACAM5 | c.1085G>A p.S362N | Missense Mutation (SNP) | VAF 70/111 reads (63%) | SIFT tolerated (0.17); PolyPhen benign (0.323); catalogued as COSV55750944; called by muse, mutect2, varscan2
- CEP192 | c.4418C>T p.T1473I | Missense Mutation (SNP) | VAF 39/62 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV58071847; called by muse, mutect2, varscan2
- CEP290 | c.3257C>T p.S1086L | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.103); catalogued as rs760934388, COSV58357676; called by mutect2, varscan2
- CES5A | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV51871677; called by muse, mutect2, varscan2
- CFAP65 | c.2479G>A p.G827S | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58567283; called by muse, mutect2, varscan2
- CFAP65 | c.657G>A p.M219I | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV55392282; called by muse, mutect2, varscan2
- CFH | c.470T>G p.I157S | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV62779118; called by muse, mutect2, varscan2
- CFTR | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as CD951654, COSV99133876, COSV99134072; called by muse, mutect2, varscan2
- CGNL1 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 75/131 reads (57%) | SIFT tolerated (0.26); PolyPhen benign (0.048); catalogued as COSV55577177; called by muse, mutect2, varscan2
- CHD2 | c.865A>T p.N289Y | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as rs145479816, COSV59122698; called by muse, mutect2, varscan2
- CHD7 | c.1762C>T p.P588S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV71115503; called by muse, mutect2, varscan2
- CHRNA9 | c.97A>C p.K33Q | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.718); catalogued as COSV59576565; called by muse, varscan2
- CHST2 | c.1202G>T p.S401I | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100535971, COSV58887423; called by muse, mutect2, varscan2
- CIT | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 51/92 reads (55%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs767424020, COSV55872238, COSV55879951; called by muse, mutect2, varscan2
- CLCA2 | c.2483C>T p.P828L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65289138; called by muse, mutect2, varscan2
- CLCA4 | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.49); catalogued as COSV65285505; called by muse, mutect2, varscan2
- CLCN7 | c.981C>T p.I327= | Splice Region (SNP) | VAF 7/50 reads (14%) | catalogued as rs776917548, COSV51971756; called by mutect2, varscan2
- CLEC5A | c.235C>T p.Q79* | Nonsense Mutation (SNP) | VAF 15/55 reads (27%) | catalogued as COSV69396800, COSV69397892; called by mutect2, varscan2
- CLN3 | c.1190C>T p.S397F (on ENST00000360019 / NM_001286104.2; = p.S421F on NM_000086.2) | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778225078, COSV61105841, COSV61108108; ClinVar: uncertain significance; called by muse, mutect2
- CMKLR1 | c.95C>T p.S32F (on ENST00000312143 / NM_001142344.2; = p.S30F on NM_004072.3) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs568799764, COSV56436126, COSV56439350; called by muse, mutect2, varscan2
- CMSS1 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1405956276, COSV70441549; called by muse, mutect2, varscan2
- CMYA5 | c.4637C>T p.S1546L | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV71410382; called by muse, mutect2, varscan2
- CNGA1 | c.1846C>T p.P616S | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs370636592, COSV62053680; called by muse, mutect2, varscan2
- CNTN1 | c.2750C>T p.S917F | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.374); catalogued as COSV61646702; called by muse, mutect2, varscan2
- CNTN3 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.301); catalogued as COSV55187612; called by muse, mutect2, varscan2
- CNTN5 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.774); catalogued as rs1010130853, COSV54303038, COSV99676123; called by muse, mutect2, varscan2
- CNTROB | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs374604826; called by mutect2, varscan2
- COG5 | c.1059G>A p.W353* | Nonsense Mutation (SNP) | VAF 56/111 reads (50%) | catalogued as COSV51767093; called by muse, mutect2, varscan2
- COG8 | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs749893629, COSV54742902, COSV99650661; called by muse, mutect2, varscan2
- COL12A1 | c.1909G>A p.D637N | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV59410939; called by muse, mutect2, varscan2
- COL17A1 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62230061; called by muse, mutect2, varscan2
- COL21A1 | c.1813G>A p.G605R | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55183085; called by muse, mutect2, varscan2
- COL21A1 | c.1346G>A p.G449E | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99777256; called by muse, mutect2, varscan2
- COL21A1 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55170002; called by muse, varscan2
- COL21A1 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.818); catalogued as COSV55183138; called by muse, varscan2
- COL22A1 | c.1751G>A p.G584E | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100276095; called by muse, mutect2, varscan2
- COL22A1 | c.1750G>A p.G584R | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs574216888, COSV57367618; called by muse, mutect2, varscan2
- COL24A1 | c.4975A>T p.K1659* | Nonsense Mutation (SNP) | VAF 29/103 reads (28%) | catalogued as COSV65316116; called by muse, mutect2, varscan2
- COL4A1 | c.3593G>A p.G1198E | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65433232; called by muse, mutect2, varscan2
- COL4A5 | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 64/64 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV100087433, COSV60374442; called by muse, mutect2, varscan2
- COL5A1 | c.3745G>A p.G1249S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65676387; called by muse, mutect2
- COL5A3 | c.3848G>A p.G1283E | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99318153; called by muse, mutect2, varscan2
- COL5A3 | c.3358C>T p.Q1120* | Nonsense Mutation (SNP) | VAF 16/21 reads (76%) | catalogued as COSV99318155; called by muse, mutect2, varscan2
- COL5A3 | c.1508G>A p.G503E | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53414295; called by muse, mutect2, varscan2
- COL6A6 | c.2156G>C p.R719P | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62016664, COSV62040144; called by muse, mutect2, varscan2
- COL8A1 | c.434T>A p.I145N | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV53744188; called by muse, mutect2, varscan2
- COL9A1 | c.1582C>T p.P528S | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.472); catalogued as COSV57886010; called by muse, mutect2, varscan2
- COLEC10 | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.212); catalogued as rs1340217222, COSV60523232; called by muse, mutect2, varscan2
- COMT | c.574C>T p.H192Y | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52891235; called by muse, mutect2
- COP1 | c.613T>C p.F205L | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV58178524; called by muse, mutect2, varscan2
- CORO7-PAM16 | c.2850G>C p.E950D | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs954393257, COSV52112293; called by muse, mutect2, varscan2
- CP | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV52834715; called by muse, mutect2, varscan2
- CPNE1 | c.127G>A p.E43K (on ENST00000352393; = p.E48K on NM_003915.5) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV58295830; called by mutect2, varscan2
- CPNE2 | c.580C>T p.H194Y | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV51965675; called by muse, mutect2, varscan2
- CPNE4 | c.180G>A p.E60= | Splice Region (SNP) | VAF 56/121 reads (46%) | catalogued as COSV70201591; called by muse, mutect2, varscan2
- CPQ | c.1415C>T p.S472F | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs763785340, COSV55164442; called by muse, mutect2, varscan2
- CPVL | c.133C>T p.L45F | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs771997351, COSV55309968; called by muse, mutect2, varscan2
- CR1 | c.2777G>A p.G926E | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65464910; called by muse, mutect2
- CR1L | c.1483C>T p.P495S | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.378); catalogued as COSV54332447; called by muse, mutect2, varscan2
- CRB1 | c.3812G>A p.G1271E | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.744); catalogued as COSV66334737; called by muse, mutect2, varscan2
- CREBBP | c.2963C>T p.P988L | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV52144202; called by muse, mutect2, varscan2
- CRNN | c.1220G>A p.G407E | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as COSV55124397, COSV99664049; called by muse, mutect2
- CRTC3 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV51595515; called by muse, mutect2, varscan2
- CRTC3 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV51596758; called by muse, mutect2, varscan2
- CRYBG1 | c.5674C>T p.P1892S | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.287); catalogued as COSV64815274; called by muse, mutect2, varscan2
- CRYGN | c.436T>C p.F146L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.025); catalogued as COSV61564510; called by muse, mutect2, varscan2
- CRYZ | c.662T>C p.I221T | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV61718961; called by muse, mutect2, varscan2
- CSF3R | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as COSV58965340; called by muse, mutect2
- CSMD1 | c.9797G>A p.G3266E (on ENST00000520002; = p.G3265E on NM_033225.6) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100145264, COSV59398048; called by muse, mutect2, varscan2
- CSMD2 | c.8012G>A p.G2671E | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53897553; called by muse, mutect2, varscan2
- CSMD2 | c.1700G>A p.W567* | Nonsense Mutation (SNP) | VAF 23/69 reads (33%) | catalogued as COSV53972812; called by muse, mutect2, varscan2
- CTNNA3 | c.2596G>A p.E866K | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.681); catalogued as COSV65530929; called by muse, mutect2, varscan2
- CTNNA3 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as COSV65530949; called by muse, mutect2, varscan2
- CTNND2 | c.1981C>T p.L661F | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58875323; called by muse, mutect2, varscan2
- CTSC | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 20/41 reads (49%) | catalogued as rs1409888746, CM002938, COSV57056428; called by mutect2, varscan2
- CUBN | c.9169G>A p.D3057N | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV64729695; called by muse, mutect2, varscan2
- CUL7 | c.2372C>T p.T791I | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV54823130; called by muse, mutect2, varscan2
- CXCR4 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54017725; called by muse, varscan2
- CYP2C8 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as rs1440353583, COSV64877869; called by muse, mutect2, varscan2
- CYP3A43 | c.174G>A p.W58* | Nonsense Mutation (SNP) | VAF 32/75 reads (43%) | catalogued as COSV55938652; called by muse, mutect2, varscan2
- CYP4A11 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.162); catalogued as COSV60226157; called by muse, mutect2, varscan2
- CYP4F11 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.123); catalogued as rs1169183019, COSV56126449; called by muse, mutect2, varscan2
- CYYR1 | c.458G>A p.R153K | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.308); catalogued as rs780556463, COSV54838993; called by muse, mutect2, varscan2
- DAO | c.166C>T p.L56F | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.6); catalogued as COSV57324902; called by muse, mutect2, varscan2
- DAPK2 | c.1097G>A p.R366K | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs765741864, COSV56044733; called by muse, mutect2, varscan2
- DCLK3 | c.1094G>A p.G365E | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101373857; called by muse, mutect2, varscan2
- DCLRE1B | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV65813800; called by muse, mutect2, varscan2
- DCX | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 69/72 reads (96%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV57568438, COSV57576414; called by muse, mutect2, varscan2
- DDX3Y | c.1208T>C p.V403A | Missense Mutation (SNP) | VAF 73/75 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV60177343; called by muse, mutect2, varscan2
- DDX46 | c.1440C>G p.Y480* | Nonsense Mutation (SNP) | VAF 44/71 reads (62%) | catalogued as COSV62801416; called by muse, mutect2, varscan2
- DDX60 | c.2836G>A p.E946K | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV67099818; called by muse, mutect2, varscan2
- DEFA3 | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV59935267; called by muse, mutect2, varscan2
- DEPDC7 | c.754G>A p.G252R (on ENST00000241051 / NM_001077242.2; = p.G243R on NM_139160.2) | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV53809647; called by muse, mutect2, varscan2
- DIDO1 | c.5870C>T p.P1957L | Missense Mutation (SNP) | VAF 70/167 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs1363137430, COSV56636076; called by muse, mutect2, varscan2
- DLEC1 | c.5191G>A p.G1731S | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.205); catalogued as rs561071711, COSV57181796; called by muse, mutect2, varscan2
- DLG2 | c.2593C>T p.P865S | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.323); catalogued as rs1170541406, COSV54665641; called by muse, mutect2, varscan2
- DLGAP1 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.179); catalogued as rs776239442, COSV100234366, COSV59795407; called by muse, mutect2
- DMBT1 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.759); catalogued as COSV57539831; called by muse, mutect2, varscan2
- DMWD | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.478); catalogued as COSV52174880; called by muse, mutect2, varscan2
- DNAAF2 | c.2168G>A p.G723D | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV100023771; called by muse, mutect2, varscan2
- DNAAF2 | c.2167G>A p.G723S | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.563); catalogued as COSV100023775; called by mutect2, varscan2
- DNAH10 | c.10346C>T p.P3449L (on ENST00000409039; = p.P3388L on NM_207437.3) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69004444; called by muse, mutect2
- DNAH10 | c.11632C>T p.P3878S (on ENST00000409039; = p.P3817S on NM_207437.3) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68995937, COSV69004457; called by muse, mutect2, varscan2
- DNAH12 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.047); catalogued as COSV100244302; called by mutect2, varscan2
- DNAH17 | c.9709G>A p.A3237T | Missense Mutation (SNP) | VAF 52/326 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67762512; called by muse, mutect2, varscan2
- DNAH17 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as rs376958134; called by mutect2, varscan2
- DNAH3 | c.9886C>T p.P3296S | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV54558621; called by muse, mutect2, varscan2
- DNAH3 | c.2825C>T p.P942L | Missense Mutation (SNP) | VAF 50/231 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54519125; called by muse, mutect2, varscan2
- DNAH5 | c.9256C>T p.L3086F | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.859); catalogued as COSV54258237; called by muse, mutect2, varscan2
- DNAH8 | c.5674G>A p.G1892S | Missense Mutation (SNP) | VAF 62/101 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748575207, COSV100545688, COSV59486356; called by muse, mutect2, varscan2
- DNAH8 | c.11260G>A p.E3754K | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs267601020, COSV59439459; called by muse, mutect2, varscan2
- DNAH9 | c.9280G>A p.E3094K | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV52376416; called by muse, mutect2, varscan2
- DNAJB11 | c.556C>T p.Q186* | Nonsense Mutation (SNP) | VAF 40/84 reads (48%) | catalogued as COSV54002281; called by muse, mutect2, varscan2
- DNAJB6 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1394317103, COSV51101426; called by muse, mutect2
- DNAJB8 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.572); catalogued as rs754445313, COSV59879639; called by muse, mutect2, varscan2
- DNAJC10 | c.2015C>T p.S672F | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs769331379, COSV51149159; called by muse, mutect2, varscan2
- DNAJC5G | c.250A>T p.I84L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV56081520; called by muse, mutect2, varscan2
- DNER | c.1957A>G p.M653V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.914); catalogued as COSV59168326, COSV59179201; called by muse, mutect2, varscan2
- DNM1 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); catalogued as rs755625989, COSV57848382, COSV57851712; called by mutect2, varscan2
- DOCK2 | c.1705C>T p.P569S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV56969466; called by muse, mutect2, varscan2
- DOCK9 | c.184A>G p.T62A (on ENST00000376460 / NM_001366676.2; = p.T63A on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.051); catalogued as COSV100237769; called by muse, mutect2, varscan2
- DOP1B | c.1858G>A p.G620S | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.419); catalogued as rs1157367666, COSV67696999; called by muse, varscan2
- DPP3 | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.152); catalogued as rs775789213, COSV59152659; called by mutect2, varscan2
- DPPA4 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as COSV59510055, COSV59512890; called by muse, mutect2, varscan2
- DPPA4 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV59509507; called by muse, mutect2, varscan2
- DSCAM | c.802T>A p.S268T | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV68038567; called by mutect2, varscan2
- DSCAML1 | c.2653G>A p.G885R (on ENST00000321322; = p.G825R on NM_020693.4) | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as rs1182451596, COSV58401230, COSV58405056; called by muse, mutect2, varscan2
- DSG3 | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57130378; called by muse, mutect2, varscan2
- DTNA | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1160999097, COSV52000112; called by mutect2, varscan2
- DUS1L | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs532728681, COSV60785509; called by muse, mutect2, varscan2
- DUSP19 | c.427-1G>A p.X143_splice | Splice Site (SNP) | VAF 48/82 reads (59%) | catalogued as COSV61194119; called by muse, varscan2
- DYNC1H1 | c.4748C>T p.S1583F | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.111); catalogued as COSV64144062; called by muse, mutect2, varscan2
- DYNC1I2 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV99783582; called by muse, mutect2, varscan2
- DYNC1I2 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV99783586; called by muse, mutect2, varscan2
- DYTN | c.1049G>A p.R350K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1481366430, COSV71751932, COSV71752730; called by muse, mutect2, varscan2
- E2F8 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51466650; called by muse, varscan2
- ECRG4 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as COSV53002040; called by mutect2, varscan2
- EDIL3 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.593); catalogued as COSV56926230; called by muse, mutect2, varscan2
- EIF4G1 | c.3790C>T p.Q1264* (on ENST00000346169 / NM_198241.3; = p.Q1069* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 24/47 reads (51%) | catalogued as COSV59994915; called by muse, mutect2, varscan2
- EIF5AL1 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.658); catalogued as rs750941729, COSV73123186; called by muse, mutect2, varscan2
- ELMO1 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.062); catalogued as COSV60296892; called by muse, mutect2, varscan2
- ELP3 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as rs775947064, COSV56457551; called by muse, mutect2, varscan2
- EMSY | c.1805C>T p.T602M | Missense Mutation (SNP) | VAF 41/57 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1489601585, COSV58266956; called by muse, mutect2, varscan2
- EMX2 | c.652G>C p.G218R | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV71294894; called by muse, mutect2
- ENAM | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 51/231 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV68537296; called by muse, mutect2, varscan2
- EPHA2 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100626351, COSV64454241; called by muse, varscan2
- EPN2 | c.1648C>T p.P550S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.37); catalogued as COSV59064084; called by muse, mutect2, varscan2
- EPS8L3 | c.1678C>T p.L560F (on ENST00000361965 / NM_133181.4; = p.L530F on NM_024526.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100719655; called by muse, mutect2, varscan2
- ERC2 | c.2125G>A p.D709N | Missense Mutation (SNP) | VAF 105/231 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs780698592, COSV55672206; called by muse, mutect2, varscan2
- ERC2 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as rs747730160, COSV55605679; called by muse, mutect2
- ERCC6 | c.2505G>A p.W835* | Nonsense Mutation (SNP) | VAF 22/75 reads (29%) | catalogued as COSV63395105; called by muse, mutect2, varscan2
- ERICH1 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs1407177274, COSV50641514; called by muse, mutect2, varscan2
- ERLIN2 | c.788A>G p.Y263C | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1331977591, COSV99379409; called by muse, mutect2, varscan2
- ERLIN2 | c.789C>A p.Y263* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV99379412; called by muse, varscan2
- ERMARD | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 15/73 reads (21%) | catalogued as COSV64651988; called by muse, mutect2, varscan2
- ERN1 | c.2042C>T p.S681F | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV70505271; called by muse, mutect2, varscan2
- ETNPPL | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as rs769718668, COSV56596691; called by muse, mutect2, varscan2
- EVPL | c.6068C>T p.S2023F | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV56906669; called by muse, mutect2, varscan2
- EXD3 | c.1981C>T p.H661Y | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59814720; called by muse, mutect2, varscan2
- EXOC4 | c.1952C>T p.S651F | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV54127515; called by muse, mutect2, varscan2
- EXPH5 | c.5252G>A p.R1751K | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.108); catalogued as COSV56209469; called by muse, mutect2, varscan2
- EXPH5 | c.4399C>T p.H1467Y | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT tolerated (1); PolyPhen possibly damaging (0.574); catalogued as COSV56209482; called by mutect2, varscan2
- EXTL3 | c.14C>T p.T5I | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.404); catalogued as COSV55040943; called by muse, mutect2, varscan2
- EYA1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 61/160 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs766713665, COSV58165683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EYA2 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as rs991612630, COSV57937794; called by muse, varscan2
- EYA2 | c.1402C>T p.P468S | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV57944969; called by muse, mutect2, varscan2
- EZHIP | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV100539444, COSV100539599; called by muse, mutect2, varscan2
- F13B | c.740T>C p.L247P | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66376072; called by muse, mutect2, varscan2
- FAM104A | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs1398298825, COSV101303950; called by muse, mutect2, varscan2
- FAM111A | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 50/76 reads (66%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV64656048; called by muse, varscan2
- FAM120A | c.2566C>T p.P856S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs1394523642, COSV52912531; called by muse, mutect2, varscan2
- FAM120B | c.1706C>T p.T569I | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.692); catalogued as COSV53008641; called by muse, mutect2, varscan2
- FAM124A | c.110C>T p.S37F (on ENST00000322475 / NM_001242312.2; = p.S73F on NM_145019.4) | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as COSV54481053; called by muse, mutect2, varscan2
- FAM135B | c.3632G>A p.R1211Q | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867471938, COSV52703558; called by mutect2, varscan2
- FAM169A | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV63064168; called by muse, varscan2
- FAM169A | c.1265C>T p.S422F | Missense Mutation (SNP) | VAF 45/64 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV63064172; called by muse, varscan2
- FAM181A | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV99967752; called by muse, mutect2, varscan2
- FAM71B | c.1625G>A p.R542K | Missense Mutation (SNP) | VAF 165/512 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as COSV57231920; called by muse, mutect2, varscan2
- FAM83C | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as COSV65584864; called by muse, mutect2, varscan2
- FAM83H | c.2506C>T p.L836F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.415); catalogued as rs781933799, COSV62030783; called by muse, mutect2
- FANCM | c.1991C>T p.S664F | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV57507996; called by muse, mutect2, varscan2
- FARSA | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 20/74 reads (27%) | catalogued as rs753322142, COSV58906296; called by muse, varscan2
- FARSB | c.1319G>A p.S440N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV56053175; called by muse, mutect2, varscan2
- FAT3 | c.5714T>C p.V1905A | Missense Mutation (SNP) | VAF 273/295 reads (93%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV53187466; called by muse, mutect2, varscan2
- FAT4 | c.3350C>T p.S1117L | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs1228464959, COSV67896482; called by muse, mutect2, varscan2
- FAT4 | c.14578G>A p.E4860K | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV58713688; called by muse, mutect2, varscan2
- FBLN1 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 20/66 reads (30%) | catalogued as rs771724672, COSV53055252; called by muse, mutect2, varscan2
- FBN2 | c.7720G>A p.E2574K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs377689621; called by muse, mutect2, varscan2
- FBXO15 | c.1343G>A p.R448K | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs763211069, COSV54049392; called by muse, mutect2, varscan2
- FBXO43 | c.1880T>C p.V627A | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV71055783; called by muse, mutect2, varscan2
- FCGR3A | c.577G>A p.G193S | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV63460783; called by muse, mutect2, varscan2
- FCGRT | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs752908319, COSV54543125, COSV54544205; called by muse, mutect2, varscan2
- FCRL1 | c.1037T>A p.L346H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.436); catalogued as COSV63828131; called by mutect2, varscan2
- FER1L6 | c.4244T>C p.F1415S | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV67553376; called by muse, varscan2
- FERMT3 | c.1186G>A p.G396R (on ENST00000279227 / NM_178443.3; = p.G392R on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV54184460, COSV99656341; called by muse, mutect2, varscan2
- FETUB | c.1006G>A p.G336R | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54005394; called by muse, mutect2, varscan2
- FGA | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV57402189; called by muse, mutect2, varscan2
- FHL5 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs747254218, COSV58735989; called by muse, mutect2, varscan2
- FKBP6 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 75/154 reads (49%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.918); catalogued as rs377226318; called by muse, mutect2, varscan2
- FLG | c.5564C>T p.S1855F | Missense Mutation (SNP) | VAF 124/300 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV64251859; called by muse, varscan2
- FLNC | c.1893G>A p.W631* | Nonsense Mutation (SNP) | VAF 50/96 reads (52%) | catalogued as COSV57967136; called by muse, mutect2, varscan2
- FLT4 | c.4015G>A p.E1339K | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.035); catalogued as rs1325967047, COSV56125303; called by muse, mutect2, varscan2
- FLT4 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV56125315; called by mutect2, varscan2
- FMN2 | c.2327G>A p.G776E | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); catalogued as COSV60459346; called by muse, mutect2, varscan2
- FOXF1 | c.582G>A p.M194I | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV52288966; called by mutect2, varscan2
- FOXK1 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1463112454, COSV61069375; called by muse, mutect2, varscan2
- FPR2 | c.115C>T p.L39F | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.194); catalogued as COSV60672072; called by muse, mutect2, varscan2
- FRAS1 | c.3280G>A p.E1094K | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as rs985853068, COSV53657010; called by mutect2, varscan2
- FRG2B | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.998); catalogued as rs1175817076, COSV71042772, COSV71044237; called by muse, mutect2, varscan2
- FRMD5 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV68726186; called by mutect2, varscan2
- FRMPD2 | c.3472G>A p.E1158K | Missense Mutation (SNP) | VAF 32/33 reads (97%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as COSV59724690; called by muse, mutect2, varscan2
- FSIP1 | c.1571C>T p.S524L | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs759273718, COSV63224438; called by mutect2, varscan2
- FSIP2 | c.18215C>T p.T6072I | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100557102, COSV58095009; called by muse, mutect2, varscan2
- FUT9 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56153992; called by mutect2, varscan2
- GABRA2 | c.1328G>A p.R443K | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as rs200987678, COSV62916606; called by muse, mutect2, varscan2
- GABRE | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 50/51 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64818853; called by muse, mutect2, varscan2
- GBP7 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV54012438; called by muse, mutect2, varscan2
- GDA | c.611C>A p.S204Y | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as COSV52998770; called by muse, mutect2, varscan2
- GDF2 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.299); catalogued as rs782195498; called by muse, mutect2, varscan2
- GFRA1 | c.1172T>C p.V391A | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV62611927; called by muse, mutect2, varscan2
- GFRAL | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs1239736348, COSV61236579; called by muse, varscan2
- GIGYF2 | c.1570G>A p.V524M | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs1213097982, COSV65254174; called by muse, mutect2, varscan2
- GIMAP4 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.065); catalogued as rs766948682, COSV55435103; called by muse, mutect2, varscan2
- GIMAP5 | c.695G>A p.R232K | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.144); catalogued as COSV57530633; called by muse, mutect2, varscan2
- GINM1 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 56/111 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV66390411; called by muse, mutect2
- GJD2 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.461); catalogued as COSV51750347; called by muse, mutect2, varscan2
- GK2 | c.1517C>A p.A506D | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104415789, COSV62628701; called by muse, mutect2, varscan2
- GLB1L2 | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 19/19 reads (100%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as COSV60281139; called by muse, mutect2, varscan2
- GNAT1 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as COSV99222245; called by muse, mutect2, varscan2
- GNG2 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58914412; called by muse, mutect2, varscan2
- GOLGA4 | c.2290C>T p.L764F | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); catalogued as rs780428861, COSV62714437; called by muse, mutect2, varscan2
- GOLIM4 | c.1069C>T p.L357F | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58331702; called by muse, mutect2, varscan2
- GPR137B | c.799C>T p.H267Y | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as COSV63991894; called by muse, mutect2, varscan2
- GPR141 | c.67C>T p.L23F | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.647); catalogued as COSV57734436; called by muse, mutect2, varscan2
- GPR156 | c.1688C>T p.S563F | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.118); catalogued as COSV59942925; called by muse, mutect2, varscan2
- GPR158 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.247); catalogued as rs1255537799, COSV66269153; called by muse, mutect2, varscan2
- GPR161 | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs868239535, COSV54791899; called by muse, mutect2, varscan2
- GPR61 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 30/55 reads (55%) | catalogued as COSV68177448; called by muse, varscan2
- GPR84 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99909923; called by mutect2, varscan2
- GPR84 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99909925; called by muse, mutect2, varscan2
- GPRC6A | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV59954039; called by muse, mutect2, varscan2
- GPS1 | c.872T>C p.I291T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.121); catalogued as COSV57651872; called by muse, mutect2, varscan2
- GRIA1 | c.2112G>A p.M704I | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV53590043; called by muse, mutect2, varscan2
- GRID1 | c.2231C>T p.A744V | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV60048574; called by muse, mutect2, varscan2
- GRID2 | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.092); catalogued as COSV99936851, COSV99947001; called by muse, mutect2, varscan2
- GRIN2A | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV58022677, COSV58055537; called by muse, mutect2, varscan2
- GRM3 | c.629G>A p.W210* | Nonsense Mutation (SNP) | VAF 28/60 reads (47%) | catalogued as COSV64481112; called by muse, mutect2, varscan2
- GRM3 | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.88); PolyPhen benign (0.155); catalogued as COSV64471988; called by muse, mutect2, varscan2
- GRM6 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99179435; called by muse, varscan2
- GSK3B | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51779816; called by muse, varscan2
- GSS | c.1172A>T p.E391V | Missense Mutation (SNP) | VAF 92/216 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV53628992; called by muse, mutect2, varscan2
- GTF3C1 | c.5729C>T p.P1910L | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV62245721; called by muse, mutect2, varscan2
- GTF3C1 | c.3710C>T p.P1237L | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV62245729; called by muse, mutect2, varscan2
- GZMA | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs267600652, COSV57050842; called by muse, mutect2, varscan2
- GZMM | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.69); PolyPhen benign (0.108); catalogued as COSV52743184; called by muse, mutect2, varscan2
- H2BC6 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.708); catalogued as rs1356715501, COSV61590843; called by muse, mutect2, varscan2
- H3-3B | c.163T>A p.Y55N | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.795); catalogued as COSV54667229; called by mutect2, varscan2
- H3C12 | c.137C>T p.T46I | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.155); catalogued as COSV58154257; called by mutect2, varscan2
- H3C4 | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.07); catalogued as COSV100587074; called by mutect2, varscan2
- HBP1 | c.1115G>A p.S372N | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV56019877; called by muse, mutect2, varscan2
- HCRTR2 | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV63794922, COSV63795120; called by muse, mutect2, varscan2
- HECTD1 | c.7780A>T p.M2594L | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (1); PolyPhen possibly damaging (0.59); catalogued as rs767188827, COSV67949729; called by muse, mutect2, varscan2
- HECW1 | c.98G>C p.R33P | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV67830108, COSV67842023; called by muse, mutect2, varscan2
- HECW1 | c.1306G>T p.E436* | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as COSV67842027; called by mutect2, varscan2
- HECW2 | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs868241529, COSV53677142; called by muse, mutect2, varscan2
- HENMT1 | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64230908; called by mutect2, varscan2
- HEPHL1 | c.1331G>A p.R444K | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT tolerated (0.94); PolyPhen benign (0.04); catalogued as COSV59897720; called by muse, mutect2, varscan2
- HGS | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as COSV61270739; called by muse, mutect2, varscan2
- HHAT | c.1087G>A p.G363R | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.105); catalogued as COSV54791162, COSV54812293; called by muse, mutect2, varscan2
- HHIPL2 | c.2074C>T p.P692S | Missense Mutation (SNP) | VAF 132/511 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58568487; called by muse, mutect2, varscan2
- HIVEP3 | c.2747C>T p.S916L | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56025605; called by mutect2, varscan2
- HMCN1 | c.10537G>A p.G3513R | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV54949594; called by muse, mutect2, varscan2
- HMCN1 | c.11218C>T p.P3740S | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54949604; called by muse, mutect2, varscan2
- HMCN1 | c.13400C>T p.P4467L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54949614; called by muse, mutect2, varscan2
- HOXA6 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.153); catalogued as COSV56071920; called by muse, mutect2, varscan2
- HOXB2 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as COSV57488529; called by muse, mutect2, varscan2
- HPS6 | c.2305C>T p.P769S | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.967); catalogued as COSV54627018; called by muse, mutect2, varscan2
- HPX | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV56419995; called by muse, mutect2, varscan2
- HRH3 | c.1048C>G p.L350V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58050921; called by muse, mutect2
- HRNR | c.3127G>A p.G1043S | Missense Mutation (SNP) | VAF 91/241 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.312); catalogued as rs1172501805, COSV64263679; called by muse, mutect2, varscan2
- HRNR | c.2036G>A p.G679E | Missense Mutation (SNP) | VAF 78/157 reads (50%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.978); catalogued as COSV64263683; called by muse, mutect2, varscan2
- HSF1 | c.968C>T p.T323I | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV60049608; called by muse, mutect2, varscan2
- HSF5 | c.1543-2A>T p.X515_splice | Splice Site (SNP) | VAF 135/228 reads (59%) | catalogued as COSV60420210; called by muse, mutect2, varscan2
- HSPA12B | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.511); catalogued as COSV99653804; called by muse, varscan2
- HTR1A | c.727G>A p.G243R | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.42); PolyPhen benign (0.287); catalogued as COSV60503484; called by muse, mutect2, varscan2
- IARS1 | c.1981C>T p.R661C | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs553833363, COSV100986768; called by mutect2, varscan2
- ICA1L | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 151/270 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs774860151, COSV64175618; called by muse, mutect2, varscan2
- ICA1L | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 247/391 reads (63%) | catalogued as COSV64173190, COSV64175626; called by muse, mutect2, varscan2
- ICAM5 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV55749755; called by muse, mutect2, varscan2
- IGBP1P2 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as rs780216124, COSV53613399; called by mutect2, varscan2
- IGFN1 | c.3201G>T p.E1067D (on ENST00000295591 / NM_001367841.1; = p.E3524D on NM_001164586.2) | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.268); catalogued as COSV55187436; called by mutect2, varscan2
- IGHMBP2 | c.2711C>T p.A904V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.219); catalogued as COSV54822124; called by muse, varscan2
- IGHV7-81 | c.197G>A p.W66* | Nonsense Mutation (SNP) | VAF 31/90 reads (34%) | catalogued as rs267603904; called by muse, mutect2, varscan2
- IGSF10 | c.1975C>T p.Q659* | Nonsense Mutation (SNP) | VAF 16/73 reads (22%) | catalogued as rs1189859410, COSV56793338; called by muse, mutect2, varscan2
- IGSF21 | c.1027G>A p.G343R | Missense Mutation (SNP) | VAF 63/115 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52127135; called by muse, mutect2, varscan2
- IGSF9 | c.386A>C p.H129P | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV63643183; called by muse, mutect2, varscan2
- IKZF2 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as rs781624972, COSV59585297; called by muse, mutect2, varscan2
- IL17RA | c.479C>T p.T160I | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.551); catalogued as COSV60056839; called by muse, varscan2
- IL20 | c.173G>A p.G58E | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65585286; called by muse, mutect2, varscan2
- IMMT | c.1152G>C p.W384C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54491066; called by muse, mutect2, varscan2
- INAVA | c.1552C>T p.P518S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as rs1557970737, COSV66256554; called by muse, mutect2, varscan2
- INO80 | c.2053C>T p.Q685* | Nonsense Mutation (SNP) | VAF 104/243 reads (43%) | catalogued as COSV62743384; called by muse, mutect2, varscan2
- INPP5D | c.452G>C p.R151P (on ENST00000445964 / NM_001017915.3; = p.R150P on NM_005541.5) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as COSV64041218; called by muse, mutect2
- INPP5J | c.2353G>A p.D785N (on ENST00000331075 / NM_001284285.2; = p.D417N on NM_001002837.2) | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1159091326, COSV53213246; called by muse, mutect2, varscan2
- INSRR | c.941G>A p.S314N | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.055); catalogued as COSV63878004; called by muse, mutect2
- INTS13 | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as rs187282284, COSV53905503; called by mutect2, varscan2
- IPP | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.89); catalogued as COSV100739357; called by mutect2, varscan2
- IPPK | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.038); catalogued as COSV55336761; called by muse, mutect2, varscan2
- IQSEC3 | c.532G>A p.G178S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.86); catalogued as COSV58285073; called by muse, mutect2, varscan2
- IRX6 | c.461C>T p.T154I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99306165; called by muse, mutect2, varscan2
- ITGA8 | c.929A>C p.Q310P | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV65237636; called by muse, mutect2, varscan2
- ITGAL | c.2473C>T p.P825S | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.012); catalogued as COSV63320752; called by muse, mutect2, varscan2
- ITIH5 | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV53675690; called by muse, mutect2, varscan2
- ITPR1 | c.7522C>T p.P2508S (on ENST00000354582; = p.P2453S on NM_002222.7) | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV57007966; called by muse, mutect2, varscan2
- ITSN1 | c.5068G>A p.G1690S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.998); catalogued as COSV67157754; called by muse, mutect2, varscan2
- IVD | c.550G>A p.E184K (on ENST00000651168; = p.E181K on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV51102595; called by muse, mutect2, varscan2
- KANSL2 | c.488G>A p.R163K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.432); catalogued as COSV63480582; called by muse, mutect2
- KCNA10 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63905559; called by muse, mutect2, varscan2
- KCND2 | c.1366C>T p.Q456* | Nonsense Mutation (SNP) | VAF 22/40 reads (55%) | catalogued as COSV58568297; called by mutect2, varscan2
- KCND3 | c.916G>A p.G306S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56191728; called by muse, mutect2, varscan2
- KCNH6 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.141); catalogued as COSV59003811; called by muse, mutect2, varscan2
- KCNJ10 | c.367C>T p.L123F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV63635286; called by muse, mutect2, varscan2
- KCNJ6 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as rs1441824370, COSV55713409, COSV55725141; called by muse, mutect2, varscan2
- KCNK10 | c.1348A>G p.T450A | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV56654235; called by muse, mutect2, varscan2
- KCNK5 | c.22C>T p.L8F | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63989543; called by muse, mutect2
- KCNN3 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); catalogued as COSV55225893; called by muse, mutect2, varscan2
- KCNQ3 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.053); catalogued as rs781473829, COSV66479687; called by muse, varscan2
- KCNV1 | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.166); catalogued as rs765968613, COSV52089705, COSV52089755; called by muse, mutect2, varscan2
- KDM2B | c.3610+2T>G p.X1204_splice | Splice Site (SNP) | VAF 14/29 reads (48%) | catalogued as COSV65645985; called by muse, mutect2, varscan2
- KDM3B | c.2054C>T p.S685F | Missense Mutation (SNP) | VAF 34/46 reads (74%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.085); catalogued as COSV58688413, COSV58696525; called by muse, mutect2, varscan2
- KEL | c.1855C>T p.P619S | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs1474469148, COSV62338522; called by muse, mutect2, varscan2
- KERA | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775457945, COSV57130302; called by muse, mutect2, varscan2
- KHDC1 | c.446G>A p.R149K (on ENST00000370384 / NM_001251874.2; = p.R76K on NM_030568.5) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.75); PolyPhen benign (0.351); catalogued as rs1315359842, COSV57616445; called by muse, mutect2, varscan2
- KIAA1109 | c.14020C>T p.R4674C | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1278017597, COSV52663636; called by muse, mutect2, varscan2
- KIAA1191 | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 21/33 reads (64%) | catalogued as rs1054413164, COSV53800429; called by muse, mutect2, varscan2
- KIAA1549L | c.920C>T p.T307I (on ENST00000321505; = p.T604I on NM_012194.3) | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV55782618; called by muse, mutect2, varscan2
- KIDINS220 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 51/78 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV56760530; called by muse, mutect2, varscan2
- KIF12 | c.1051G>A p.E351K (on ENST00000640217; = p.E213K on NM_138424.1) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV65118626; called by mutect2, varscan2
- KIF12 | c.919G>A p.D307N (on ENST00000640217; = p.D169N on NM_138424.1) | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.137); catalogued as COSV100936034, COSV65118635; called by muse, mutect2, varscan2
- KLF17 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.039); catalogued as COSV64857270; called by muse, mutect2, varscan2
- KLF6 | c.754C>T p.R252* | Nonsense Mutation (SNP) | VAF 28/47 reads (60%) | catalogued as COSV51494344; called by muse, mutect2, varscan2
- KLHL36 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50726023; called by muse, mutect2, varscan2
- KLHL38 | c.1398G>A p.M466I | Missense Mutation (SNP) | VAF 77/161 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV58089600; called by mutect2, varscan2
- KLHL6 | c.1838G>A p.R613K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV58069994; called by muse, mutect2, varscan2
- KLRC4 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs976566332, COSV58672048; called by muse, mutect2, varscan2
- KMT2C | c.5209A>G p.K1737E | Missense Mutation (SNP) | VAF 130/264 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51514995; called by muse, mutect2, varscan2
- KPRP | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV64221571; called by muse, mutect2, varscan2
- KRIT1 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1164308092, COSV60669585; called by muse, mutect2, varscan2
- KRT1 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV52870170; called by muse, mutect2, varscan2
- KRT33A | c.178A>C p.M60L | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.253); catalogued as COSV50377768; called by muse, varscan2
- KRT33A | c.138G>T p.W46C | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV50377933; called by muse, varscan2
- KRT39 | c.40A>G p.T14A | Missense Mutation (SNP) | VAF 83/172 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs891506787, COSV62917625; called by muse, mutect2, varscan2
- KRT73 | c.1072C>T p.Q358* | Nonsense Mutation (SNP) | VAF 21/45 reads (47%) | catalogued as COSV59838155; called by muse, mutect2, varscan2
- KRT8 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs1316915181, COSV53179639; called by muse, mutect2, varscan2
- KRT83 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV53343051; called by muse, mutect2, varscan2
- KRTAP5-11 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); catalogued as COSV59369737, COSV59371638; called by muse, mutect2, varscan2
- KRTAP5-11 | c.253T>A p.S85T | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.01); catalogued as COSV100651705; called by muse, mutect2, varscan2
- LACRT | c.254-1G>C p.X85_splice | Splice Site (SNP) | VAF 28/76 reads (37%) | catalogued as COSV57688970; called by muse, mutect2, varscan2
- LACTB | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as COSV56057206; called by muse, mutect2, varscan2
- LAMA1 | c.4072C>T p.L1358F | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT tolerated (0.12); PolyPhen benign (0.087); catalogued as COSV67545591; called by muse, mutect2
- LCK | c.1345G>A p.V449M | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60743241; called by muse, mutect2, varscan2
- LIFR | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV54694102; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as COSV53287364; called by muse, mutect2, varscan2
- LLGL2 | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.681); catalogued as COSV51418295; called by muse, mutect2, varscan2
- LLGL2 | c.1190C>T p.P397L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs893540567, COSV51418322; called by muse, mutect2, varscan2
- LLGL2 | c.2567C>T p.A856V | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99388850; called by muse, mutect2, varscan2
- LNX1 | c.1306G>A p.D436N (on ENST00000263925 / NM_001126328.3; = p.D340N on NM_032622.2) | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV55792891; called by muse, mutect2, varscan2
- LRCH4 | c.238T>G p.F80V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV53830676; called by muse, mutect2, varscan2
- LRIG2 | c.1930C>T p.P644S | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63160903; called by muse, mutect2, varscan2
- LRP1B | c.12398C>T p.P4133L | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs754228687, COSV67254925, COSV67285007; called by muse, mutect2, varscan2
- LRP1B | c.10444C>T p.Q3482* | Nonsense Mutation (SNP) | VAF 45/85 reads (53%) | catalogued as rs757539493, COSV67208435, COSV67285011; called by muse, mutect2, varscan2
- LRP1B | c.10232C>T p.P3411L | Missense Mutation (SNP) | VAF 43/70 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1396148040, COSV67285015; called by muse, mutect2, varscan2
- LRP1B | c.2701A>T p.K901* | Nonsense Mutation (SNP) | VAF 29/71 reads (41%) | catalogued as COSV63342064; called by muse, mutect2
- LRP5 | c.1636C>T p.P546S | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs774097621, COSV53715971; called by muse, varscan2
- LRRC17 | c.1031T>G p.L344R | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV50868987; called by muse, mutect2, varscan2
- LRRC37A3 | c.3374C>T p.P1125L | Missense Mutation (SNP) | VAF 98/400 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV58537462; called by muse, mutect2, varscan2
- LRRC4B | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.957); catalogued as COSV65350106; called by mutect2, varscan2
- LRRC4C | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV53440703; called by muse, mutect2, varscan2
- LRRC66 | c.1307C>T p.P436L | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV58635995, COSV58637339; called by muse, mutect2, varscan2
- LRRC8E | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 48/81 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60719484, COSV60719505; called by muse, mutect2, varscan2
- LRRIQ4 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61620505; called by muse, mutect2, varscan2
- LRRK2 | c.2690-1G>A p.X897_splice | Splice Site (SNP) | VAF 9/17 reads (53%) | catalogued as COSV54174829; called by muse, mutect2, varscan2
- LRRK2 | c.6576G>A p.E2192= | Splice Region (SNP) | VAF 11/32 reads (34%) | catalogued as COSV54174849; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 77/325 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as COSV65443258; called by muse, mutect2, varscan2
- LY9 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as COSV54438683; called by muse, mutect2, varscan2
- LY9 | c.1384A>C p.M462L | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54438694; called by muse, mutect2, varscan2
- LYN | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.99); PolyPhen benign (0.007); catalogued as COSV70205430; called by muse, mutect2, varscan2
- LYST | c.11189T>G p.I3730S | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV67715723; called by muse, mutect2, varscan2
- LZTR1 | c.729C>A p.F243L | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV53152585; called by muse, mutect2, varscan2
- MACF1 | c.21189T>A p.F7063L (on ENST00000372915; = p.F5108L on NM_012090.5) | Missense Mutation (SNP) | VAF 79/112 reads (71%) | catalogued as COSV57149748; called by muse, mutect2, varscan2
- MACROD2 | c.461A>T p.N154I | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV54068566; called by muse, mutect2, varscan2
- MAEL | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.156); catalogued as rs754539955, COSV63112374; called by mutect2, varscan2
- MAGEA3 | c.883G>A p.G295R | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV64756644; called by muse, mutect2, varscan2
- MAGEB6B | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as rs1373579889; called by muse, mutect2, varscan2
- MAGEC2 | c.460C>T p.L154F | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.527); catalogued as COSV55997733; called by muse, mutect2, varscan2
- MAGI1 | c.449G>A p.R150K | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.269); catalogued as COSV58349137; called by muse, mutect2, varscan2
- MANEA | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as COSV62590839; called by muse, mutect2, varscan2
- MAP1LC3B2 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs866294489, COSV61009640; called by muse, mutect2, varscan2
- MAP4K1 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.024); catalogued as COSV101204121; called by muse, mutect2, varscan2
- MAP4K3 | c.1954C>T p.P652S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.919); catalogued as COSV55719937; called by muse, mutect2, varscan2
- MAP7 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV63418665; called by muse, mutect2, varscan2
- MARCHF2 | c.508C>T p.H170Y | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.52); PolyPhen benign (0.185); catalogued as COSV53107145; called by muse, mutect2
- MARK2 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59290068; called by muse, mutect2, varscan2
- MB21D2 | c.1400G>A p.G467E | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104433116, COSV66666587; called by muse, mutect2, varscan2
- MBD3 | c.874T>A p.*292Kext*24 | Nonstop Mutation (SNP) | VAF 11/24 reads (46%) | catalogued as COSV50086341; called by muse, varscan2
- MCMDC2 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs1459675743, COSV58042013; called by muse, mutect2, varscan2
- MCOLN2 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV99393558; called by muse, mutect2, varscan2
- MCOLN2 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV99393560; called by muse, mutect2, varscan2
- MECOM | c.1586C>T p.S529L (on ENST00000468789 / NM_001105078.4; = p.S717L on NM_004991.4) | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs1169063502, COSV52966929; called by muse, mutect2, varscan2
- MED12L | c.1626G>A p.E542= | Splice Region (SNP) | VAF 17/30 reads (57%) | catalogued as COSV56401013; called by muse, mutect2, varscan2
- MEGF8 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV99234227; called by muse, mutect2
- MEI1 | c.1229C>T p.S410L | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.099); catalogued as COSV55900098, COSV55908966; called by mutect2, varscan2
- METRNL | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 77/126 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0.288); catalogued as COSV60762040; called by muse, varscan2
- METTL22 | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV50838988; called by muse, mutect2, varscan2
- MGA | c.2293C>T p.L765F | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.155); catalogued as rs775510278, COSV54960102, COSV99578313; called by muse, mutect2, varscan2
- MICAL3 | c.5111C>T p.S1704F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV101490794, COSV71588764; called by muse, mutect2, varscan2
- MICU1 | c.614C>T p.S205F (on ENST00000361114 / NM_001195518.2; = p.S211F on NM_006077.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV63148531; called by muse, mutect2
- MICU1 | c.80T>G p.I27S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as COSV63148538; called by muse, mutect2, varscan2
- MKI67 | c.1114A>G p.R372G | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV64077633; called by muse, mutect2, varscan2
- MMP27 | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs865798287, COSV52780904; called by muse, mutect2
- MMRN1 | c.2636C>T p.S879L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV53337958, COSV99306255; called by muse, mutect2, varscan2
- MORC1 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.08); catalogued as COSV51716373, COSV51722300; called by muse, mutect2, varscan2
- MPHOSPH10 | c.1957C>T p.Q653* | Nonsense Mutation (SNP) | VAF 19/59 reads (32%) | catalogued as rs867713680, COSV54917300; called by muse, mutect2, varscan2
- MR1 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs759016009, COSV51582485; called by mutect2, varscan2
- MTBP | c.1825T>C p.Y609H | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV59967253; called by muse, mutect2, varscan2
- MTMR14 | c.1610C>T p.P537L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV56008262; called by muse, mutect2, varscan2
- MTMR4 | c.574A>G p.K192E | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.241); catalogued as COSV60204643; called by muse, mutect2, varscan2
- MUC16 | c.42551A>G p.D14184G | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.985); catalogued as COSV66697589; called by muse, mutect2, varscan2
- MUC16 | c.36398C>T p.P12133L | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV101202135, COSV67501649; called by muse, mutect2, varscan2
- MUC16 | c.30724G>A p.G10242R | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as rs763871277, COSV67501654; called by muse, mutect2, varscan2
- MUC16 | c.18352C>T p.P6118S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs546618826, COSV67442656; called by muse, varscan2
- MUC16 | c.8305G>A p.E2769K | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV67501677; called by muse, mutect2, varscan2
- MUC17 | c.7351C>T p.P2451S | Missense Mutation (SNP) | VAF 100/404 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs750904683, COSV60307177; called by muse, mutect2, varscan2
- MUC17 | c.7888G>A p.E2630K | Missense Mutation (SNP) | VAF 156/337 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.636); catalogued as COSV60294980; called by muse, mutect2, varscan2
- MUC17 | c.9227C>T p.P3076L | Missense Mutation (SNP) | VAF 151/318 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.908); catalogued as COSV60307200; called by muse, mutect2, varscan2
- MUC17 | c.12148G>A p.E4050K | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV60307222; called by muse, mutect2, varscan2
- MUC3A | c.8914C>T p.L2972F | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as COSV100113851, COSV100115127; called by muse, mutect2
- MUC5B | c.5554G>A p.E1852K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV71596598; called by muse, mutect2, varscan2
- MUC6 | c.3791C>T p.P1264L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV101424388; called by muse, mutect2, varscan2
- MXRA5 | c.6583G>A p.D2195N | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV54232108; called by muse, mutect2, varscan2
- MYBPC2 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV63092994; called by muse, mutect2, varscan2
- MYD88 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57181802; called by muse, mutect2, varscan2
- MYH1 | c.5716G>A p.E1906K | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.573); catalogued as rs368680249; called by muse, mutect2, varscan2
- MYH2 | c.3346G>A p.E1116K | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV55432052, COSV55450802; called by muse, mutect2, varscan2
- MYO15A | c.3580G>A p.E1194K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV52764946; called by muse, mutect2, varscan2
- MYO1G | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.401); catalogued as rs1210310349, COSV51856966; called by muse, mutect2, varscan2
- MYOM2 | c.3095T>G p.V1032G | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50794602; called by muse, varscan2
- MYRF | c.782C>T p.S261F (on ENST00000278836 / NM_001127392.3; = p.S252F on NM_013279.4) | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754453884, COSV53895135; called by muse, mutect2, varscan2
- MYT1L | c.50T>C p.V17A | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV67735020; called by muse, mutect2, varscan2
- N4BP2L2 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 68/141 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs761044155, COSV99912399; called by muse, mutect2, varscan2
- NAA11 | c.100C>T p.H34Y | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV54515287; called by muse, varscan2
- NACA2 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 43/242 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV71713212; called by muse, mutect2, varscan2
- NAGA | c.1141C>T p.R381* | Nonsense Mutation (SNP) | VAF 37/78 reads (47%) | catalogued as rs750450177, COSV67170111; called by muse, mutect2, varscan2
- NAP1L2 | c.823A>G p.K275E | Missense Mutation (SNP) | VAF 34/34 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.099); catalogued as COSV65173178; called by muse, mutect2, varscan2
- NAV1 | c.1783G>A p.G595S | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.98); catalogued as rs747791930, COSV55213874; called by muse, mutect2, varscan2
- NAV3 | c.5897T>C p.F1966S (on ENST00000397909 / NM_001024383.2; = p.F1944S on NM_014903.6) | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.958); catalogued as COSV57118063; called by muse, mutect2, varscan2
- NBEA | c.410G>A p.W137* | Nonsense Mutation (SNP) | VAF 68/129 reads (53%) | catalogued as COSV59830979; called by muse, mutect2, varscan2
- NBEA | c.4879C>T p.L1627F | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.969); catalogued as COSV59758802, COSV59803756; called by muse, mutect2, varscan2
- NCKAP1L | c.2753G>A p.R918K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV53213638; called by muse, mutect2, varscan2
- NCOA2 | c.2323C>T p.P775S | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.986); catalogued as COSV71765222; called by muse, mutect2, varscan2
- NCOA6 | c.4682A>G p.H1561R | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV62868901; called by muse, mutect2, varscan2
- NCR1 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.114); catalogued as COSV52555622; called by muse, mutect2, varscan2
- NDNF | c.1462A>C p.N488H | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV65634981; called by muse, mutect2, varscan2
- NDUFAF2 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV56944703; called by muse, mutect2, varscan2
- NEB | c.7186G>A p.D2396N | Missense Mutation (SNP) | VAF 98/140 reads (70%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs867897450, COSV51078603; called by muse, mutect2, varscan2
- NEK1 | c.2248G>A p.E750K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.08); catalogued as COSV71458404; called by muse, varscan2
- NEK11 | c.1076A>G p.K359R | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV63584345; called by muse, mutect2, varscan2
- NEK2 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs768444644, COSV65357719; called by muse, mutect2, varscan2
- NELFB | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV58026752; called by muse, mutect2, varscan2
- NF1 | c.7739-1G>A p.X2580_splice (on ENST00000358273 / NM_001042492.3; = p.X2559_splice on NM_000267.3) | Splice Site (SNP) | VAF 66/152 reads (43%) | catalogued as COSV62191760, COSV62215400; called by muse, mutect2, varscan2
- NFASC | c.665C>T p.T222I (on ENST00000339876 / NM_001378329.1; = p.T216I on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV58384487; called by muse, mutect2, varscan2
- NFATC1 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.64); catalogued as COSV53711105; called by mutect2, varscan2
- NFATC3 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV60481035; called by muse, mutect2, varscan2
- NKAIN2 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as COSV63695338; called by muse, mutect2, varscan2
- NLN | c.1153C>T p.P385S | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV66767514; called by muse, mutect2, varscan2
- NLRC3 | c.1180C>A p.R394S | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV57096902; called by muse, varscan2
- NLRP12 | c.2507G>A p.G836E | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.995); catalogued as COSV100144968, COSV60743784; called by muse, mutect2, varscan2
- NLRP12 | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs1210179524, COSV100144783; called by muse, mutect2, varscan2
- NLRP13 | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as COSV100738204, COSV61624477; called by muse, mutect2, varscan2
- NLRP3 | c.1550G>A p.S517N | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60232410; called by muse, mutect2, varscan2
- NLRP8 | c.2535G>A p.S845= | Splice Region (SNP) | VAF 101/174 reads (58%) | catalogued as rs759573457, COSV52595387; called by muse, mutect2, varscan2
- NME6 | c.257T>C p.L86P (on ENST00000415053; = p.L94P on NM_005793.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56641147; called by muse, mutect2, varscan2
- NOBOX | c.292G>A p.G98S | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.051); catalogued as rs775041573, COSV56192593, COSV56198589, COSV56199608; called by muse, mutect2, varscan2
- NOTCH1 | c.6679C>T p.P2227S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs757213098, COSV53063547; called by muse, mutect2, varscan2
- NOX5 | c.1633C>T p.Q545* | Nonsense Mutation (SNP) | VAF 15/31 reads (48%) | catalogued as COSV52997606; called by mutect2, varscan2
- NPAP1 | c.2492C>T p.S831F | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.053); catalogued as COSV61512468; called by muse, mutect2, varscan2
- NPM2 | c.512A>C p.K171T | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV57076881; called by muse, mutect2, varscan2
- NPNT | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as rs754036065, COSV59754008; called by muse, mutect2
- NPY1R | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV56714916, COSV56716927; called by muse, mutect2, varscan2
- NR1I2 | c.832G>A p.G278R | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs976156170, COSV61979992; called by muse, mutect2, varscan2
- NR5A2 | c.1178G>A p.R393Q (on ENST00000367362 / NM_205860.3; = p.R347Q on NM_003822.5) | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.782); catalogued as rs772993318, COSV52659226; called by muse, varscan2
- NRG3 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.992); catalogued as rs1023059995, COSV64542403; called by muse, mutect2, varscan2
- NUP214 | c.4157C>T p.P1386L | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.242); catalogued as COSV100845120; called by muse, mutect2, varscan2
- NWD1 | c.3880C>T p.P1294S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs746678087, COSV60349838; called by muse, mutect2, varscan2
- OBSCN | c.7213C>T p.P2405S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.649); catalogued as COSV52842320; called by muse, mutect2, varscan2
- OPRPN | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 18/58 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV68192596; called by mutect2, varscan2
- OR11H4 | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.364); catalogued as COSV59561080; called by muse, mutect2, varscan2
- OR13C2 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as rs747135132, COSV73377666; called by muse, mutect2, varscan2
- OR1C1 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV101376297, COSV68715746; called by muse, mutect2, varscan2
- OR1L8 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as COSV59185844, COSV59187647; called by muse, mutect2, varscan2
- OR2A25 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV68717791; called by muse, mutect2, varscan2
- OR2C1 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1161658977, COSV59241583; called by muse, mutect2, varscan2
- OR2C3 | c.491C>T p.T164I | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as COSV63576672; called by muse, mutect2, varscan2
- OR2G2 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as rs1184093466, COSV60742690; called by muse, mutect2, varscan2
- OR2T6 | c.455G>A p.G152E | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1020868114, COSV100861473, COSV63217211; called by muse, mutect2, varscan2
- OR4C16 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as rs1256354622, COSV58940623, COSV58940762; called by muse, mutect2, varscan2
- OR4K15 | c.691T>C p.S231P (on ENST00000305051; = p.S207P on NM_001005486.1) | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV59303833; called by muse, mutect2, varscan2
- OR4M1 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 54/252 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV60060181, COSV60061234; called by muse, mutect2, varscan2
- OR4N2 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 54/299 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as COSV60054383; called by muse, mutect2, varscan2
- OR4N2 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 39/253 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as rs763828281, COSV60055727; called by muse, mutect2, varscan2
- OR4S2 | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 44/45 reads (98%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV100412876, COSV56748672; called by muse, mutect2, varscan2
- OR51M1 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 107/243 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as rs866442558, COSV60785779; called by muse, mutect2, varscan2
- OR52A1 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV61091897; called by muse, mutect2, varscan2
- OR52D1 | c.634C>A p.L212M | Missense Mutation (SNP) | VAF 70/153 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.462); catalogued as COSV59488616; called by muse, mutect2, varscan2
- OR52H1 | c.940G>A p.G314R (on ENST00000322653; = p.G320R on NM_001005289.1) | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100497347, COSV59506393; called by muse, mutect2, varscan2
- OR52I1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 70/146 reads (48%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV56170469; called by muse, mutect2, varscan2
- OR52R1 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs866371519, COSV61888830; called by muse, mutect2
- OR56A1 | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs763572368, COSV57362486; called by mutect2, varscan2
- OR5B12 | c.469C>T p.H157Y | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.029); catalogued as COSV56905030, COSV56906809; called by mutect2, varscan2
- OR5B12 | c.189C>G p.N63K | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV56907069; called by muse, mutect2, varscan2
- OR5D14 | c.454C>T p.L152F | Missense Mutation (SNP) | VAF 43/56 reads (77%) | SIFT tolerated (0.41); PolyPhen benign (0.033); catalogued as COSV59457772; called by muse, mutect2, varscan2
- OR5H1 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV63403672; called by muse, varscan2
- OR5P3 | c.536G>C p.C179S | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV60430166; called by muse, mutect2, varscan2
- OR5R1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.588); catalogued as COSV56571496; called by muse, mutect2, varscan2
- OR8K3 | c.841A>C p.I281L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.724); catalogued as COSV57133475; called by muse, mutect2, varscan2
- ORAI3 | c.281T>C p.L94P | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52693575; called by muse, mutect2, varscan2
- OTOA | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as rs746967874, COSV53749783; called by muse, mutect2, varscan2
- OTOL1 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60008818; called by mutect2, varscan2
- OTX2 | c.731G>A p.G244E (on ENST00000408990 / NM_172337.3; = p.G252E on NM_021728.4) | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV59768013; called by muse, mutect2, varscan2
- OVCH2 | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0.029); catalogued as rs1161947189, COSV71952809; called by muse, mutect2, varscan2
- P3H2 | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 74/188 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV60019863; called by muse, mutect2, varscan2
- P3H2 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV60029284; called by muse, mutect2, varscan2
- PAK5 | c.1702G>A p.D568N | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62025659; called by muse, mutect2, varscan2
- PAN3 | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV99144502; called by muse, mutect2, varscan2
- PAN3 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV99144503; called by mutect2, varscan2
- PAPPA | c.3569G>A p.S1190N | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.99); catalogued as rs1266238638, COSV60293909; called by muse, mutect2, varscan2
- PAPPA | c.4157C>T p.S1386F | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs929769049, COSV60288527; called by muse, mutect2, varscan2
- PAPSS2 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63265448; called by muse, mutect2, varscan2
- PARD6B | c.95T>A p.L32Q | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65405426; called by muse, mutect2, varscan2
- PARP10 | c.839C>T p.T280I | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs374158798; called by muse, mutect2, varscan2
- PARVG | c.982G>A p.G328R | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as rs754198891, COSV63563280; called by muse, mutect2, varscan2
- PCARE | c.1934G>A p.R645K | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as COSV59058968; called by muse, mutect2, varscan2
- PCDH15 | c.4072G>C p.E1358Q | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs766259569, COSV100219399, COSV57410863; called by muse, mutect2, varscan2
- PCDH18 | c.1897C>T p.P633S | Missense Mutation (SNP) | VAF 72/168 reads (43%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.589); catalogued as COSV61272796; called by muse, mutect2, varscan2
- PCDHA2 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.022); catalogued as COSV65366595; called by muse, mutect2, varscan2
- PCDHA5 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 44/73 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65357335; called by muse, mutect2, varscan2
- PCDHA5 | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs782404545, COSV65359306; called by muse, mutect2, varscan2
- PCDHA8 | c.1621G>A p.G541S | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65334059; called by muse, mutect2, varscan2
- PCDHB15 | c.1136G>A p.G379E | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV51427805, COSV99179341; called by muse, mutect2, varscan2
- PCDHB16 | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); catalogued as COSV53361002, COSV53363010; called by mutect2, varscan2
- PCDHB5 | c.2278G>A p.A760T | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV50678451; called by muse, mutect2, varscan2
- PCDHGA1 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.58); catalogued as rs1232947431, COSV65294958, COSV65300482; called by muse, mutect2, varscan2
- PCDHGA1 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 63/88 reads (72%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.124); catalogued as rs759644223, COSV65295915, COSV65298942; called by muse, mutect2, varscan2
- PCK1 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs146652385; called by muse, mutect2, varscan2
- PCK1 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60131629; called by muse, mutect2, varscan2
- PCK1 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60125929, COSV60131638; called by muse, mutect2, varscan2
- PCLO | c.10958C>T p.P3653L | Missense Mutation (SNP) | VAF 83/167 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV61675970; called by muse, mutect2, varscan2
- PCLO | c.9364C>T p.H3122Y | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.439); catalogued as rs1370031106, COSV61618618; called by mutect2, varscan2
- PCNX2 | c.5614G>A p.D1872N | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.357); catalogued as COSV50940401; called by muse, mutect2, varscan2
- PCYT1B | c.470T>C p.F157S | Missense Mutation (SNP) | VAF 23/24 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63266916; called by muse, mutect2, varscan2
- PDE8B | c.1600C>T p.L534F | Missense Mutation (SNP) | VAF 115/329 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.67); catalogued as COSV53747442; called by muse, mutect2, varscan2
- PDGFC | c.409G>A p.G137R | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs774202989, COSV56844988, COSV56856450; called by muse, mutect2, varscan2
- PDZRN3 | c.2763G>A p.W921* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV55218655; called by muse, mutect2, varscan2
1,173 further variants in this file (466 protein-altering or splice-affecting, 662 silent, 45 other) are not listed here.
